Somatic mutation profile of cancer-model specimen HCM-WCMC-1287-C67-85A (3D Organoid; aliquot HCM-WCMC-1287-C67-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-1287-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Combined small cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 74.8 years (27,327 days).
Specimen HCM-WCMC-1287-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8f89bf4-7c25-4f21-b9ac-264f93ffc152.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1287-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-1287-C67-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/758b1ebd-7cd7-48f3-9cdd-0013938d9b48

The open-access MAF lists 153 somatic variants for this specimen: 109 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 41, Nonsense Mutation 9, Splice Site 4, Frame Shift Ins 3, Intron 2, Splice Region 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPC1 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 182/359 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs483352891, CM146762; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 596/597 reads (100%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 86/414 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV51443682; called by muse, mutect2, varscan2
- ACOXL | c.1544A>G p.Y515C (on ENST00000389811 / NM_001371254.1; = p.Y485C on NM_001142807.4) | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs370944721; called by muse, mutect2, varscan2
- ADM | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 30/862 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53402991; called by muse, mutect2
- BBS12 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 256/470 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58562107; called by muse, mutect2, varscan2
- CAPN12 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 122/465 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs1393042922; called by muse, mutect2, varscan2
- COL6A5 | c.3740C>T p.A1247V | Missense Mutation (SNP) | VAF 198/393 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557597562, COSV55209835; called by muse, mutect2, varscan2
- CRACD | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 275/557 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757293190; called by muse, mutect2, varscan2
- DNAH3 | c.6763T>C p.Y2255H | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766728991; called by muse, mutect2, varscan2
- DOK2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs867550583, COSV52387505; called by muse, mutect2, varscan2
- DPY19L3 | c.1993A>G p.M665V | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.874); catalogued as rs199792338; called by muse, mutect2, varscan2
- DSCAML1 | c.4311C>A p.N1437K (on ENST00000321322; = p.N1377K on NM_020693.4) | Missense Mutation (SNP) | VAF 196/419 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs755146000; called by muse, mutect2, varscan2
- FAT4 | c.5458C>T p.L1820F | Missense Mutation (SNP) | VAF 225/432 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1251905201; called by muse, mutect2, varscan2
- GRAMD1C | c.1492C>T p.Q498* | Nonsense Mutation (SNP) | VAF 68/390 reads (17%) | catalogued as COSV63983229; called by muse, mutect2, varscan2
- KLF4 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 167/694 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs761126579, COSV101012654; called by muse, mutect2, varscan2
- LHCGR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 332/646 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs979633619, COSV54295551, COSV54300568; called by muse, mutect2, varscan2
- LIN28A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 47/423 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV54261846; called by muse, mutect2, varscan2
- MIDN | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 234/524 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99960482; called by muse, mutect2
- MRPS18B | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 246/900 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs759454468; called by muse, mutect2
- NABP2 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 29/487 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs755241303, COSV57191091; called by muse, mutect2
- NEBL | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 177/406 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1443675600, COSV101009211; called by muse, mutect2, varscan2
- NIBAN1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 136/662 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as COSV62284224; called by muse, mutect2, varscan2
- NUCB1 | c.480G>A p.T160= | Splice Region (SNP) | VAF 70/278 reads (25%) | catalogued as rs1345057334, COSV54386942; called by muse, mutect2, varscan2
- OR4K2 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53848214; called by mutect2, varscan2
- PCDHA2 | c.1320C>G p.S440R | Missense Mutation (SNP) | VAF 213/582 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.338); catalogued as rs1554119811; called by muse, mutect2, varscan2
- PCNT | c.9273C>T p.S3091= | Splice Region (SNP) | VAF 26/323 reads (8%) | catalogued as rs764829521; called by muse, mutect2
- PDPR | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs1420270253; called by muse, mutect2, varscan2
- PEX5 | c.1837A>G p.M613V (on ENST00000420616; = p.M605V on NM_000319.5) | Missense Mutation (SNP) | VAF 463/811 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs765623850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIAS2 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs1330207201; called by mutect2, varscan2
- PRDM14 | c.1339C>A p.L447I | Missense Mutation (SNP) | VAF 142/339 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99400502; called by muse, mutect2, varscan2
- PSMD11 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV55581887; called by muse, mutect2
- SI | c.4427G>A p.G1476E | Missense Mutation (SNP) | VAF 171/327 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as CM1213018, COSV52274082; called by muse, mutect2, varscan2
- SLC24A5 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1408506794; called by muse, mutect2, varscan2
- SLC27A2 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 201/462 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51062527; called by muse, mutect2, varscan2
- SUPT6H | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 102/475 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs762812168, COSV58931545; called by muse, mutect2, varscan2
- SYCP2 | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 126/316 reads (40%) | catalogued as COSV62771703; called by muse, mutect2, varscan2
- TET1 | c.4165G>A p.D1389N | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV65385092; called by muse, mutect2
- TNXB | c.3947C>T p.T1316M (on ENST00000647633; = p.T1069M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/562 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs755472309; called by muse, mutect2, varscan2
- WNT5B | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 179/958 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs749761500; called by muse, mutect2, varscan2
- ZBTB32 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 327/713 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233708222; called by muse, mutect2, varscan2
- ZFHX2 | c.4393C>A p.P1465T | Missense Mutation (SNP) | VAF 32/603 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs766492038; called by muse, mutect2
- ZNF775 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 385/795 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs749944741; called by muse, mutect2, varscan2
- ACSL1 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 180/348 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOLD1 | c.346C>G p.L116V (on ENST00000326765 / NM_001130415.2; = p.L85V on NM_030817.3) | Missense Mutation (SNP) | VAF 188/877 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ARHGAP45 | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 20/425 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATAT1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 211/724 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC3 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 296/601 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- C8orf82 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 386/762 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, mutect2
- C8orf82 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 404/842 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.218); called by muse, mutect2
- CCKBR | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 56/302 reads (19%) | called by muse, mutect2, varscan2
- CELF6 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 155/688 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP43 | c.137A>T p.N46I | Missense Mutation (SNP) | VAF 175/279 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHPF2 | c.2037C>G p.Y679* | Nonsense Mutation (SNP) | VAF 400/794 reads (50%) | called by muse, mutect2, varscan2
- CMYA5 | c.9784C>G p.L3262V | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTPS1 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.281); called by muse, mutect2
- FLG | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 52/886 reads (6%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.766); called by muse, mutect2
- FOXF2 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 184/582 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- FRMPD1 | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 234/502 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GCC2 | c.5024C>G p.S1675C | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HCN1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 266/470 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HIRA | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 100/348 reads (29%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 208/435 reads (48%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 160/235 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNU1 | c.2737-1G>T p.X913_splice | Splice Site (SNP) | VAF 65/418 reads (16%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 189/844 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KLF4 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 150/665 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- KMT2A | c.5016_5035dup p.S1679Kfs*35 | Frame Shift Ins (INS) | VAF 90/275 reads (33%) | called by mutect2, varscan2
- LPIN1 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 158/677 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- MAP3K20 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MUC16 | c.8620G>C p.A2874P | Missense Mutation (SNP) | VAF 156/366 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2
- MVB12B | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- MYO19 | c.520A>T p.N174Y | Missense Mutation (SNP) | VAF 105/419 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NIM1K | c.877C>A p.H293N | Missense Mutation (SNP) | VAF 69/587 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOM1 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 198/394 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OXTR | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 200/417 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- PABPC4 | c.649dup p.T217Nfs*30 | Frame Shift Ins (INS) | VAF 69/263 reads (26%) | called by mutect2, pindel, varscan2
- PARP14 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 279/594 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH11X | c.95A>C p.E32A | Missense Mutation (SNP) | VAF 316/317 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX3 | c.4276G>C p.G1426R | Missense Mutation (SNP) | VAF 189/727 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLPPR1 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 154/319 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PPP1R3A | c.2026A>G p.I676V | Missense Mutation (SNP) | VAF 222/478 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPP1R9B | c.1549dup p.A517Gfs*31 | Frame Shift Ins (INS) | VAF 301/728 reads (41%) | called by mutect2, pindel, varscan2
- PRIMPOL | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RASA1 | c.2827C>A p.L943I | Missense Mutation (SNP) | VAF 140/217 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RYR2 | c.8432G>A p.S2811N | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- SAMD1 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 83/439 reads (19%) | called by muse, mutect2, varscan2
- SCN5A | c.4013T>G p.L1338R (on ENST00000333535 / NM_198056.3; = p.L1337R on NM_000335.5) | Missense Mutation (SNP) | VAF 132/647 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEMA3A | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SLC16A12 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 219/340 reads (64%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.496); called by muse, mutect2
- SLC49A3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 168/743 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SMG1 | c.1946T>C p.V649A | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORCS1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 138/451 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- SULF2 | c.1380+1G>A p.X460_splice | Splice Site (SNP) | VAF 91/339 reads (27%) | called by muse, mutect2, varscan2
- TAF4B | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 238/457 reads (52%) | called by muse, mutect2, varscan2
- TCHHL1 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 242/452 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TENM2 | c.7345G>A p.G2449S (on ENST00000518659 / NM_001122679.2; = p.G2210S on NM_001080428.3) | Missense Mutation (SNP) | VAF 71/457 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TMEM131 | c.4505C>A p.P1502Q | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2
- TMEM65 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 22/445 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- TRAPPC8 | c.1669_1710del p.V557_R570del | In Frame Del (DEL) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- TTYH1 | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 393/848 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE2A | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 189/190 reads (99%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- UPP2 | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 257/418 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTRN | c.3973del p.X1325_splice | Splice Site (DEL) | VAF 112/255 reads (44%) | called by mutect2, pindel, varscan2
- VARS2 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 358/705 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZFP30 | c.459C>A p.N153K | Missense Mutation (SNP) | VAF 250/472 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF71 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 149/797 reads (19%) | called by muse, mutect2, varscan2
- ZNF729 | c.2401T>C p.C801R | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- ABCB1 | c.264G>A p.L88= | Silent (SNP) | VAF 137/289 reads (47%) | called by muse, mutect2, varscan2
- ATP2A3 | c.1860C>T p.R620= | Silent (SNP) | VAF 155/760 reads (20%) | catalogued as rs143693514; called by muse, mutect2, varscan2
- BAHCC1 | c.4737G>A p.L1579= | Silent (SNP) | VAF 173/640 reads (27%) | called by muse, mutect2, varscan2
- CD320 | c.411C>T p.L137= | Silent (SNP) | VAF 256/573 reads (45%) | called by muse, mutect2, varscan2
- CDHR4 | c.1956G>A p.R652= | Silent (SNP) | VAF 95/512 reads (19%) | called by muse, mutect2, varscan2
- CDK11B | c.1254C>G p.L418= | Silent (SNP) | VAF 60/800 reads (8%) | catalogued as rs1046458106; called by muse, mutect2
- CDKL5 | c.615C>T p.S205= | Silent (SNP) | VAF 168/327 reads (51%) | catalogued as rs1273092102; called by muse, mutect2, varscan2
- CLEC16A | c.949C>T p.L317= | Silent (SNP) | VAF 68/237 reads (29%) | called by muse, mutect2, varscan2
- CTDSP2 | c.30G>T p.A10= | Silent (SNP) | VAF 123/422 reads (29%) | catalogued as COSV67726998; called by muse, mutect2, varscan2
- DNAH10 | c.13107C>T p.F4369= (on ENST00000409039; = p.F4308= on NM_207437.3) | Silent (SNP) | VAF 57/343 reads (17%) | catalogued as rs780939265; called by muse, mutect2, varscan2
- DNAH5 | c.1707A>G p.L569= | Silent (SNP) | VAF 162/350 reads (46%) | called by muse, mutect2, varscan2
- DSEL | c.2886A>G p.A962= | Silent (SNP) | VAF 233/476 reads (49%) | called by muse, mutect2, varscan2
- FNDC7 | c.1041T>C p.Y347= | Silent (SNP) | VAF 89/482 reads (18%) | called by muse, mutect2, varscan2
- GALNT18 | c.1806G>A p.L602= | Silent (SNP) | VAF 106/482 reads (22%) | catalogued as rs137911823; called by muse, mutect2
- GOLGA8M | c.891G>A p.P297= | Silent (SNP) | VAF 197/527 reads (37%) | catalogued as rs1187561670; called by muse, mutect2, varscan2
- IRGQ | c.810G>A p.P270= | Silent (SNP) | VAF 158/661 reads (24%) | catalogued as rs776059259; called by muse, mutect2, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 120/425 reads (28%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2, varscan2
- KAT6B | c.1926G>A p.Q642= | Silent (SNP) | VAF 106/359 reads (30%) | called by muse, mutect2, varscan2
- LILRA5 | c.390C>T p.P130= | Silent (SNP) | VAF 257/532 reads (48%) | catalogued as rs756572938; called by muse, mutect2, varscan2
- LPO | c.1164C>T p.R388= | Silent (SNP) | VAF 123/479 reads (26%) | catalogued as rs753533769; called by muse, mutect2, varscan2
- MX1 | c.1209G>A p.L403= | Silent (SNP) | VAF 105/351 reads (30%) | catalogued as rs901873414; called by muse, mutect2, varscan2
- NEB | c.15342C>A p.S5114= | Silent (SNP) | VAF 102/311 reads (33%) | called by mutect2, varscan2
- NEB | c.10632G>A p.P3544= | Silent (SNP) | VAF 98/353 reads (28%) | catalogued as rs200043736; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PIEZO2 | c.2043C>T p.A681= | Silent (SNP) | VAF 305/602 reads (51%) | called by muse, mutect2, varscan2
- PLCB1 | c.3498G>A p.Q1166= | Silent (SNP) | VAF 96/469 reads (20%) | called by muse, mutect2, varscan2
- POLQ | c.834G>A p.L278= | Silent (SNP) | VAF 262/542 reads (48%) | called by muse, mutect2, varscan2
- PPP2R1A | c.858C>T p.A286= | Silent (SNP) | VAF 13/443 reads (3%) | called by muse, mutect2
- PRB4 | c.639C>A p.P213= | Silent (SNP) | VAF 362/915 reads (40%) | catalogued as rs996264922, COSV54400979; called by muse, mutect2, varscan2
- RIC3 | c.480C>G p.A160= | Silent (SNP) | VAF 210/464 reads (45%) | called by muse, mutect2, varscan2
- RTN4RL1 | c.111G>A p.T37= | Silent (SNP) | VAF 164/670 reads (24%) | catalogued as rs781616813; called by muse, mutect2, varscan2
- SORCS3 | c.1128T>C p.C376= | Silent (SNP) | VAF 20/383 reads (5%) | called by muse, mutect2
- SPATA31D1 | c.4545C>T p.P1515= | Silent (SNP) | VAF 315/632 reads (50%) | called by muse, mutect2, varscan2
- STAMBP | c.441G>A p.Q147= | Silent (SNP) | VAF 149/614 reads (24%) | called by muse, mutect2, varscan2
- SULF1 | c.1836C>G p.V612= | Silent (SNP) | VAF 78/429 reads (18%) | called by muse, mutect2, varscan2
- SUPT6H | c.1243C>A p.R415= | Silent (SNP) | VAF 103/469 reads (22%) | called by muse, mutect2, varscan2
- SYNE1 | c.23799G>A p.Q7933= (on ENST00000367255 / NM_182961.4; = p.Q7862= on NM_033071.3) | Silent (SNP) | VAF 42/250 reads (17%) | called by muse, mutect2, varscan2
- TEAD4 | c.738G>A p.L246= | Silent (SNP) | VAF 114/519 reads (22%) | called by muse, mutect2, varscan2
- TUBA3D | c.48C>T p.I16= | Silent (SNP) | VAF 127/419 reads (30%) | catalogued as rs767332287; called by muse, mutect2, varscan2
- UCMA | c.84T>C p.S28= | Silent (SNP) | VAF 168/326 reads (52%) | called by muse, varscan2
- VCAN | c.1578C>T p.I526= | Silent (SNP) | VAF 233/358 reads (65%) | catalogued as rs1410187149, COSV54116141; called by muse, mutect2, varscan2
- ZNF454 | c.153C>G p.V51= | Silent (SNP) | VAF 199/496 reads (40%) | catalogued as COSV100194530, COSV100195199, COSV60770681; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+7500T>C | Intron (SNP) | VAF 51/352 reads (14%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+1075C>G | Intron (SNP) | VAF 237/1055 reads (22%) | catalogued as COSV100424311, COSV58519019; called by muse, mutect2, varscan2
- NBPF25P | n.438C>T | RNA (SNP) | VAF 109/455 reads (24%) | called by muse, mutect2, varscan2
